MMRF case MMRF_1496 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/de405770-7784-4ca2-991f-2dee14ef221b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 494 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 39.9 years (14,564 days); ISS stage: III; Days to last known disease status: 494 days (1.4 years); Days to last follow up: 494 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 60 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 121 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 293 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 453 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 320 days; Days to treatment end: 342 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 320 days; Days to treatment end: 370 days (1.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 342 days; Days to treatment end: 423 days (1.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 383 days (1.0 years); Days to treatment end: 423 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: Second line of therapy; Days to treatment start: 427 days (1.2 years); Days to treatment end: 427 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 494.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1: M Protein 5.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 82.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.243 g/L; Beta 2 Microglobulin 7.4 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 6.5 ×10⁹/L; Platelets 37 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.75 mmol/L; Albumin 41 g/L; Total Protein 13.8 g/dL; Glucose 6.05 mmol/L.
- Day 89: M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 9.53 g/L; Immunoglobulin A 0.414 g/L; Immunoglobulin M 2.08 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 149 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.662 g/L; Immunoglobulin M 0.679 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 7.98 mmol/L.
- Day 266 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.44 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.444 g/L; Immunoglobulin M 0.572 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 49 g/L; Total Protein 8 g/dL; Glucose 5.83 mmol/L.
- Day 370 (ECOG 1): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 39.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 0.67 ×10⁹/L; Platelets 12 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 9.6 g/dL; Glucose 5.72 mmol/L.
- Day 461 (ECOG 2): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 18.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -1: Weight: 90 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (6 samples)
- Sample MMRF_1496_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1496_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
- Sample MMRF_1496_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 266 days.
- Sample MMRF_1496_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 370 days (1.0 years).
- Sample MMRF_1496_3_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Days to sample procurement: 370 days (1.0 years).
- Sample MMRF_1496_3_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 370 days (1.0 years).
